Surgical pathology report (de-identified scan), TCGA case TCGA-GV-A6ZA, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Cleveland Clinic, specimen TCGA-GV-A6ZA-01A (Primary Tumor).

[page 1 of 4]
Results**SURGICAL PATHOLOGY****Patient Info**

Sex

DOB

Results

Specimen #:

Submitting Physician:

**FINAL DIAGNOSIS**

1. Left distal ureter, excision (A) - Markedly denuded ureter.
- Negative for neoplasm.
2. Right distal ureter, excision (B) - Ureter negative for dysplasia and/or neoplasia.
3. Right pelvic wall, biopsy (C) - Benign fibromuscular tissue with myxoid changes.
4. Urethral margin, excision (D) - Urethra negative for dysplasia and/or neoplasia
5. Pelvic lymph nodes, excision (E) - Twelve lymph nodes, negative for carcinoma (0/12).
6. Bladder and prostate, radical cystoprostatectomy (F) - Invasive high-grade papillary urothelial carcinoma with focal glandular differentiation. (See comment)
- Tumor invades muscularis propria (detrusor muscle).
- Cystitis cystica et glandularis with mucinous metaplasia
- Ureteral, urethral and soft tissue margins of resection are negative for tumor.
7. Prostate, radical cystoprostatectomy (F) - Minute focus of adenocarcinoma of the prostate, Gleason score 3+3=6. (See comment)
- Focal high-grade prostatic intraepithelial neoplasia.
- Tumor is confined to the prostate.
- Seminal vesicles are negative for tumor.
- Surgical margins of resection are negative for tumor.

ICD-O-3

Carcinoma, urothelial papillary
8/30/13

Site Bladder NOS
267.9

path
Overlapping lesion of bladder
262.8
9/8/11/13

COMMENT

6. Procedure: Radical cystoprostatectomy

Tumor Size (greatest dimension): 3.5 cm

Histologic Type: Urothelial carcinoma with glandular differentiation

Associated epithelial lesion: Cystitis cystica et glandularis with mucinous metaplasia

Histologic grade (Urothelial Carcinoma, WHO 2004/ISUP): High-grade

Adenocarcinoma and Squamous Carcinoma: Not applicable.

Microscopic Tumor Extension: Tumor invades muscularis propria (detrusor

[page 2 of 4]
muscle)

Margins: Margins uninvolved by invasive carcinoma
Lymphovascular Invasion: Not identified

Pathologic Stage (TNM): pT2b N0 MX

Number lymph nodes examined: 12

Number lymph nodes involved (any size): 0

7. Procedure: Radical prostatectomy with pelvic lymph node dissection

Prostate Size: 4.5 x 4.0 x 3.0 cm

Prostate Weight: N/A

Histologic Type: Adenocarcinoma (acinar, not otherwise specified)

Gleason score: Primary 3, Secondary 3, Tertiary 0

Total Gleason Score: 6

% of 4 and/or 5: 0%

% of 3: 100%

Areas of involvement: Right anterolateral mid peripheral zone

Principal area of involvement: Right anterolateral mid peripheral zone

Focality: Unifocal

Proportion (percentage) of prostate involved by tumor: <1%

Greatest dimension of larger tumor nodule: 1 mm

Treatment effect on carcinoma: Not identified

Extraprostatic extension (EPE): Not identified

Seminal vesicles invasion (SVI): Not identified

Margins: Margins uninvolved by invasive carcinoma

Lymphovascular invasion: Not identified

Lymph nodes: (see above)

Diameter of largest lymph node metastasis (mm): N/A

Additional Pathologic Findings:

- Benign prostatic hyperplasia
- Multifocal atrophy with acute and chronic inflammation
- Atherosclerosis of periprostatic vessels

Pathologic Stage (pTNM): pT2 N0 MX

The diagnosis of carcinoma is supported by the failure of immunoperoxidase staining for p63 to demonstrate basal cells in the atypical glands.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by

The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

(Electronic Signature)

SPECIMEN SUBMITTED

- A: LEFT DISTAL URETER
- B: RIGHT DISTAL URETER
- C: RIGHT PELVIC WALL
- D: URETHRAL MARGIN
- E: PELVIC LYMPH NODE
- F: BLADDER AND PROSTATE

[page 3 of 4]
CLINICAL DATA
BLADDER CANCER

INTRAOPERATIVE CONSULT DIAGNOSIS

- A. Denuded mucosa. Negative for neoplasm
- B. Negative for neoplasm
- C. Fibrous adhesions, negative for neoplasm
- D. Negative for neoplasm

GROSS DESCRIPTION

A. Received fresh for intraoperative consultation labeled "left distal ureter" is tan-brown soft tissue with a lumen measuring 0.5 x 0.2 x 0.2 cm. It is totally submitted as FSA1.

B. Received fresh for intraoperative consultation labeled "right distal ureter" is tan-brown soft tissue with a lumen measuring 1.0 x 0.5 x 0.3 cm. It is totally submitted as FSB1.

C. Received fresh for intraoperative consultation labeled "right pelvic wall" is one piece of tan-red soft tissue measuring 0.6 x 0.3 x 0.2 cm. It is totally submitted for frozen section as FSC1.

D. Received fresh for intraoperative consultation labeled "urethral margin" is one piece of tan-brown soft tissue with a lumen which measures 0.8 x 0.5 x 0.3 cm. It is totally submitted for frozen section as FSD1.

E. Received in formalin labeled "left pelvic lymph nodes" are multiple fragments of yellow-tan fibroadipose tissue aggregating to 7.0 x 5.2 x 3.1 cm. Sectioning reveals multiple ovoid tan firm nodules resembling lymph nodes ranging in size from 0.5 to 4.3 cm. The nodules are submitted as follows: E1 five nodules, E2 two nodules, E3 one nodule, E4 one nodule bisected, E5 one nodule bisected, E6-E7 one nodule sectioned, E8-E10 largest nodule sectioned.

F. Received in formalin is a specimen labeled "bladder and prostate". The specimen consists of a urinary bladder, bilateral ureters, prostate, attached seminal vesicles and vas deferentia. The bladder measures 7.5 x 3.0 x 5.0 cm. The exterior surface is covered by a smooth serosal lining at the dome and fibroadipose tissue at the remaining portion. After the bladder is opened, two exophytic tan-brown fungating masses are identified. The first mass involves the left wall and anterior wall and measures 3.5 x 3.0 x 2.5 cm. The second mass involves the right wall of the bladder and measures 3.5 x 2.5 x 2.0 cm. Upon sectioning, the first mass on the left side of the bladder grossly appears to invade into the muscular bladder wall but not through the wall. It does not appear to involve the perivesical adipose tissue. The second mass, located on the right side of the bladder, does not grossly invade into the wall. The dome of the bladder and the posterior bladder mucosa are not involved. A segment of right ureter measures 1.7 cm in length, is patent and unremarkable. A segment of left ureter measuring 2.7 cm in length is patent and grossly unremarkable. The prostate measures 4.5 cm transversely, 4.0 cm anteroposteriorly, and 3.0 cm craniocaudally. The capsular surface is smooth. The gland is inked

[page 4 of 4]
Encounter Date:

blue on the right and yellow on the left. After fixation, the capsular surface is retracted and partially detached. The gland is sectioned from apex to base transversely at 3 mm intervals. The cross sections do not reveal a mass. No nodularity is present. The seminal vesicles are unremarkable. Representative sections are submitted as follows: F1 section of urethra, F2 random section of right ureter, F3 random section of left ureter, F4 left wall of bladder with invasive mass, F5 left wall of bladder deep aspect of invasive mass (deep to section F4), F6 anterior bladder with invasive mass, F7-F8 right wall with second mass and deep inked margins, F9 dome, F10 posterior between masses, F11 trigone, F12 prostate right apex, F13 left apex, F14 6 mm right, F15 6 mm left, F16 9 mm right anterior, F17 9 mm left anterior, F18 9 mm right posterior, F19 9 mm left posterior, F20 24 mm right inferior, F21 24 mm left inferior, F22 24 mm right posterior, F23 24 mm left posterior, F24 right seminal vesicle, F25 left seminal vesicle. The remainder of the prostate is submitted on per request of as follows: F 26 12 mm right anterior, F27 12 mm left anterior, F28 12 mm right posterior, F29 12 mm left posterior, F30 15 mm anterior right, F31 15 mm anterior left, F32 15 mm posterior right, F33 15 mm posterior left, F34, 21 mm anterior right, F35 21 mm anterior left, F36 21 mm posterior right, F37 21 mm posterior left. Also, an additional section of left ureter is submitted as F38.

Submitted by:

Location:

Test performed by:

Lab and Collection

SURGICAL PATHOLOGY

Lab and Collection Information

Result History

SURGICAL PATHOLOGY

Order Result History Report

Result Information

Result Date and Time

Status

Provider Status

Final result

Ordered

Status:

This result is currently not released to

Display Full Result Report

Display Order Report

Series	hw 7/26/13	Yes	No
RNAA Discrepancy			
Prior Pathology History			
Qual/Sync/Conc Primary Note	Discrepancy		

Source: NCI Genomic Data Commons file 9f41632e-38e9-4941-b808-4cb0f20b612e (TCGA-GV-A6ZA.7FF8C90D-50A3-435B-B3C9-306DC4973DC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).